Somatic mutation profile of tumor specimen C3N-02324-03 (aliquot CPT0135040009) from CPTAC case C3N-02324, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 38.6 years (14,084 days).
Specimen C3N-02324-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80700dd0-6243-459c-a174-66eab770cd60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02324-71 (Blood Derived Normal), aliquot CPT0135140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/725a3771-b0b9-4ef1-ab36-2e1433f4788c

The open-access MAF lists 741 somatic variants for this specimen: 467 protein-altering or splice-affecting, 244 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 423, Silent 244, Nonsense Mutation 24, Intron 17, Splice Region 7, 3'UTR 6, Frame Shift Del 4, Splice Site 4, In Frame Del 3, 5'Flank 3, RNA 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC47 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 52/205 reads (25%) | catalogued as rs1269750663, COSV99854157; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.3220G>A p.G1074S | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs587779554, CM1412698, COSV58584727; ClinVar: pathogenic; called by muse, mutect2
- GBA | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 124/796 reads (16%) | catalogued as rs121908309, CM940811, CX165705, COSV59169115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58051188; called by muse, mutect2, varscan2
- ABCD4 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs747033918; called by muse, mutect2, varscan2
- ADGRA1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 272/329 reads (83%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs758993127, COSV63416765; called by muse, mutect2, varscan2
- AP000812.4 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 263/329 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV56191907; called by muse, mutect2, varscan2
- AQP7 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 297/375 reads (79%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV53028694; called by muse, mutect2, varscan2
- ARGFX | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 143/211 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs772436631; called by muse, mutect2, varscan2
- ASPM | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 180/668 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs150684410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXDND1 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1355006662; called by muse, mutect2, varscan2
- BAIAP3 | c.882G>A p.W294* | Nonsense Mutation (SNP) | VAF 266/490 reads (54%) | catalogued as COSV100181462; called by muse, mutect2, varscan2
- BAIAP3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 76/756 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs145863608; called by muse, mutect2
- BCLAF1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 94/495 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV62140252; called by muse, mutect2, varscan2
- BDP1 | c.7666C>T p.R2556* | Nonsense Mutation (SNP) | VAF 267/527 reads (51%) | catalogued as rs746088956, COSV62432459; called by muse, mutect2, varscan2
- BIRC7 | c.217G>C p.A73P | Missense Mutation (SNP) | VAF 153/772 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as rs764398536; called by muse, mutect2, varscan2
- BRINP3 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 236/400 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1462039922, COSV66526256; called by muse, mutect2, varscan2
- C12orf54 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 83/333 reads (25%) | catalogued as COSV100011702; called by muse, mutect2, varscan2
- C1orf94 | c.1670C>T p.P557L (on ENST00000488417 / NM_001134734.2; = p.P367L on NM_032884.5) | Missense Mutation (SNP) | VAF 129/434 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs1022690522; called by muse, mutect2, varscan2
- CACNA1E | c.6373G>A p.G2125S (on ENST00000367573 / NM_001205293.3; = p.G2082S on NM_000721.4) | Missense Mutation (SNP) | VAF 170/576 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs1242442958, COSV62406630; called by muse, mutect2, varscan2
- CACNB1 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 258/515 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV59999928; called by muse, mutect2, varscan2
- CACNG5 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 112/466 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV50056062; called by muse, mutect2, varscan2
- CALB2 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 202/448 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs150780459; called by muse, mutect2, varscan2
- CASKIN1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 216/535 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV58876346; called by muse, mutect2, varscan2
- CASP12 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65259780; called by muse, mutect2, varscan2
- CATSPERB | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 154/533 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1303094175; called by muse, mutect2, varscan2
- CDH18 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 72/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759919566, COSV56916333; called by muse, mutect2, varscan2
- CDH23 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as rs750201320; called by muse, mutect2, varscan2
- CDH9 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV50290079, COSV99142890; called by muse, mutect2, varscan2
- CFHR4 | c.155C>T p.S52F (on ENST00000367416 / NM_001201551.2; = p.S53F on NM_006684.5) | Missense Mutation (SNP) | VAF 170/589 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1167567203; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 155/240 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CLCNKB | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 97/543 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1216820934, COSV65161099; called by muse, mutect2, varscan2
- CLEC17A | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 109/440 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100355182; called by muse, mutect2, varscan2
- CNR1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 237/408 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1265926769, COSV62987426; called by muse, mutect2, varscan2
- CNTNAP4 | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571000371, COSV56664435; called by muse, mutect2, varscan2
- COL1A1 | c.3077G>A p.R1026Q | Missense Mutation (SNP) | VAF 110/396 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56807887; called by muse, mutect2, varscan2
- COL9A3 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 205/517 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); catalogued as rs759377762; called by muse, mutect2, varscan2
- CR2 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 366/611 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as COSV65506401; called by muse, mutect2, varscan2
- CRYBG2 | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as rs1337752891; called by muse, mutect2, varscan2
- CSMD1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 123/298 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs770518582, COSV68166947; called by muse, mutect2, varscan2
- CTAGE6 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs755445996; called by muse, varscan2
- CUBN | c.4072C>T p.P1358S | Missense Mutation (SNP) | VAF 252/784 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV64714746, COSV64722810; called by muse, mutect2, varscan2
- CYP19A1 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV53058702; called by muse, mutect2, varscan2
- CYP2C19 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100990579, COSV64907233; called by muse, mutect2, varscan2
- DDX1 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246288; called by muse, mutect2, varscan2
- DLX2 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 97/467 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774531942; called by muse, mutect2, varscan2
- DMAC1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 471/548 reads (86%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs950230683, COSV64065607; called by muse, mutect2, varscan2
- DNAH10 | c.3034G>A p.E1012K (on ENST00000409039; = p.E951K on NM_207437.3) | Missense Mutation (SNP) | VAF 200/407 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as rs371847081; called by muse, mutect2, varscan2
- DNAH11 | c.10536G>A p.M3512I | Missense Mutation (SNP) | VAF 79/427 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs759819257, COSV60960070; called by muse, mutect2, varscan2
- DNAH5 | c.10772G>A p.G3591E | Missense Mutation (SNP) | VAF 228/571 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54214966, COSV99451847; called by muse, mutect2, varscan2
- DOCK7 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52003311; called by muse, mutect2, varscan2
- DSG4 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 105/347 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57390916; called by muse, mutect2, varscan2
- DSP | c.8371C>T p.R2791C | Missense Mutation (SNP) | VAF 256/602 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867430601, COSV100673059, COSV60938692; called by muse, mutect2, varscan2
- EPHA6 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 481/592 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV101064793; called by muse, mutect2, varscan2
- ERBB2 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 106/427 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54062745; called by muse, mutect2, varscan2
- ERN2 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 88/356 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166620834; called by muse, mutect2, varscan2
- ERVMER34-1 | c.638G>A p.W213* | Nonsense Mutation (SNP) | VAF 171/442 reads (39%) | catalogued as rs897252967; called by muse, mutect2, varscan2
- F11 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 126/240 reads (53%) | catalogued as rs281875279, CM990520; called by muse, mutect2, varscan2
- FAM47C | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV63727780; called by muse, mutect2, varscan2
- FARSA | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 214/509 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108715; called by muse, mutect2, varscan2
- FBN1 | c.4181G>A p.G1394E | Missense Mutation (SNP) | VAF 96/490 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100354228, COSV57312093; called by muse, mutect2, varscan2
- FIGN | c.1916C>T p.S639F | Missense Mutation (SNP) | VAF 317/597 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100293101; called by muse, mutect2, varscan2
- FLT1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as COSV56744768; called by muse, mutect2, varscan2
- FRAS1 | c.10075C>T p.P3359S | Missense Mutation (SNP) | VAF 228/416 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1334473449; called by muse, mutect2, varscan2
- FSIP2 | c.5105G>A p.G1702E | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs900003193; called by muse, mutect2, varscan2
- GABRG1 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.593); catalogued as rs1408329621, COSV54960467; called by muse, mutect2, varscan2
- GARS1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769780656, COSV66828115; called by muse, mutect2, varscan2
- GDF5 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 324/784 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.808); catalogued as COSV65499450; called by muse, mutect2, varscan2
- GJD2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 700/980 reads (71%) | SIFT tolerated (0.44); PolyPhen benign (0.084); catalogued as COSV99290711; called by muse, mutect2
- GPAT3 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 107/202 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV100023351; called by muse, mutect2, varscan2
- GPR52 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 490/830 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170872463, COSV52308291; called by muse, mutect2, varscan2
- GRB14 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs748901643; called by muse, mutect2, varscan2
- GRIN2A | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 124/397 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV58025546; called by muse, mutect2, varscan2
- GRIN2A | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 116/413 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58022258; called by muse, varscan2
- GRIN3B | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 374/813 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs528711346; called by muse, mutect2, varscan2
- GRXCR1 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 143/493 reads (29%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.658); catalogued as COSV67674746; called by muse, mutect2, varscan2
- GYS2 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 97/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750540143, COSV53928064; called by muse, mutect2, varscan2
- HDAC9 | c.2225G>A p.W742* | Nonsense Mutation (SNP) | VAF 141/397 reads (36%) | catalogued as COSV101286866; called by muse, mutect2, varscan2
- HERC2 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 295/940 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV55349970; called by muse, mutect2, varscan2
- HERC6 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 98/412 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs751533234; called by muse, mutect2, varscan2
- HTR1D | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 475/655 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs776156764, COSV58448643; called by muse, mutect2, varscan2
- HYAL2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 121/325 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs782218795; called by muse, mutect2, varscan2
- HYDIN | c.10520C>T p.P3507L | Missense Mutation (SNP) | VAF 121/362 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770764287; called by muse, mutect2, varscan2
- HYDIN | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 115/547 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.12); catalogued as rs1207757687, COSV55479303; called by muse, mutect2, varscan2
- IFNAR1 | c.1144-1G>A p.X382_splice | Splice Site (SNP) | VAF 32/95 reads (34%) | catalogued as COSV54253527; called by muse, mutect2, varscan2
- IGHG4 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 358/862 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777861581; called by muse, mutect2, varscan2
- IPO4 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1273079370, COSV55781454; called by muse, mutect2, varscan2
- KHDRBS2 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1163838503; called by muse, mutect2, varscan2
- KHDRBS2 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 136/459 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1408764252, COSV55468978; called by muse, mutect2, varscan2
- KRT82 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 117/458 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as rs1162132514, COSV57786357; called by muse, mutect2, varscan2
- KRTAP4-5 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 358/726 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs750199140, COSV58352140; called by muse, mutect2, varscan2
- LAMA3 | c.2802G>A p.M934I | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs369862625; called by muse, mutect2, varscan2
- LCT | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 121/823 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); catalogued as rs753114284, COSV51546508; called by muse, mutect2, varscan2
- LIMK1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 281/523 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as rs458683; called by muse, mutect2, varscan2
- LMF1 | c.900C>T p.A300= | Splice Region (SNP) | VAF 112/429 reads (26%) | catalogued as rs773190273; called by muse, mutect2, varscan2
- LOXHD1 | c.5611G>A p.E1871K (on ENST00000642948; = p.E1809K on NM_144612.7) | Missense Mutation (SNP) | VAF 312/455 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56061153; called by muse, mutect2, varscan2
- LRP1B | c.4078G>A p.E1360K | Missense Mutation (SNP) | VAF 143/493 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67184575; called by muse, mutect2, varscan2
- LRP3 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 112/491 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs765998277; called by muse, mutect2, varscan2
- LRRC37A3 | c.3515G>A p.R1172K | Missense Mutation (SNP) | VAF 159/605 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV58534756; called by muse, mutect2, varscan2
- LRRC43 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.214); catalogued as rs751280120, COSV60290496; called by muse, mutect2, varscan2
- LRRIQ1 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 77/294 reads (26%) | catalogued as rs1382081755, COSV67830032; called by muse, mutect2, varscan2
- LRRIQ1 | c.4864G>A p.E1622K | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs757710968; called by muse, mutect2, varscan2
- MAB21L4 | c.1333G>A p.E445K (on ENST00000388934 / NM_001085437.3; = p.E277K on NM_024861.4) | Missense Mutation (SNP) | VAF 100/261 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs374811918; called by muse, mutect2, varscan2
- MDGA1 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 330/749 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99777179; called by muse, mutect2, varscan2
- MECR | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 208/624 reads (33%) | catalogued as rs1162224576, COSV55285527; called by muse, mutect2, varscan2
- MEMO1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767724176; called by muse, mutect2, varscan2
- MET | c.3640G>A p.E1214K | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs1261418076, COSV100576986, COSV59266477; ClinVar: uncertain significance; called by muse, varscan2
- MIA3 | c.4682C>T p.S1561L | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750915810, COSV100485200; called by muse, mutect2, varscan2
- MIB2 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 177/1044 reads (17%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as rs759114968; called by muse, mutect2, varscan2
- MSR1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026742; called by muse, mutect2, varscan2
- MYOCD | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 133/324 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58505054; called by muse, mutect2, varscan2
- MYOM2 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 158/424 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as rs772216538, COSV100038274, COSV50783662; called by muse, mutect2, varscan2
- NAA40 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 108/293 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1274067850; called by muse, mutect2, varscan2
- NAV2 | c.1369C>T p.P457S (on ENST00000396087 / NM_001244963.2; = p.P434S on NM_145117.5) | Missense Mutation (SNP) | VAF 138/358 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as rs560572869; called by mutect2, varscan2
- NBEAL1 | c.5242C>T p.R1748* | Nonsense Mutation (SNP) | VAF 150/262 reads (57%) | catalogued as rs964194129, COSV71374624; called by muse, mutect2, varscan2
- NCOR2 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 134/417 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1321107170; called by mutect2, varscan2
- NCOR2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 104/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970975674; called by muse, mutect2, varscan2
- NFASC | c.2303G>A p.R768K (on ENST00000339876 / NM_001378329.1; = p.R764K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 242/825 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs557773864; called by muse, mutect2, varscan2
- NOTCH2 | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 103/1159 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV56681386; called by muse, mutect2
- NOVA1 | c.1376A>T p.K459I | Missense Mutation (SNP) | VAF 235/386 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57476229; called by muse, mutect2, varscan2
- NXPH3 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 397/687 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs547958058; called by muse, mutect2, varscan2
- OPN4 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 271/352 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760979172, COSV54119845, COSV99618349; called by muse, mutect2, varscan2
- OR10S1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 270/355 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV101602490, COSV73342758; called by muse, mutect2, varscan2
- OR11H1 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 111/366 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1354826500, COSV99421760; called by muse, mutect2, varscan2
- OR11H1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 110/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381294770; called by muse, mutect2, varscan2
- OR2A2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 140/477 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68872002; called by muse, mutect2, varscan2
- OR2A25 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 199/348 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs781424500; called by muse, mutect2, varscan2
- OR4K2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 73/449 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); catalogued as rs756950043, COSV53848625; called by muse, mutect2, varscan2
- OTOGL | c.1321G>A p.E441K (on ENST00000547103; = p.E432K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as rs768136183; called by muse, mutect2, varscan2
- PAK5 | c.1830G>A p.M610I | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62024616, COSV62040886; called by muse, mutect2, varscan2
- PASD1 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 135/164 reads (82%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.015); catalogued as rs868089742, COSV100949569, COSV64855582; called by muse, mutect2, varscan2
- PCCA | c.2111C>T p.T704I | Missense Mutation (SNP) | VAF 153/199 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as rs759569756; called by muse, mutect2, varscan2
- PCDH10 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52102157; called by muse, varscan2
- PCDHA7 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 269/810 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782412740, COSV100971442; called by muse, mutect2, varscan2
- PCDHA8 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 331/642 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV65334627; called by muse, mutect2, varscan2
- PDE1C | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 149/249 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs914671037, COSV58507877; called by muse, mutect2, varscan2
- PDS5A | c.2261T>C p.L754P | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV57831058; called by muse, mutect2, varscan2
- PIK3C2G | c.4195G>A p.G1399S (on ENST00000676171; = p.G1358S on NM_004570.5) | Missense Mutation (SNP) | VAF 154/274 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56825051; called by muse, mutect2, varscan2
- PIP5K1B | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 112/573 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55257119; called by muse, mutect2, varscan2
- PIWIL3 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs149968553, COSV59993666; called by muse, mutect2, varscan2
- PLCZ1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV56852789; called by muse, mutect2, varscan2
- PLEKHG4B | c.3280G>A p.A1094T (on ENST00000283426; = p.A1450T on NM_052909.5) | Missense Mutation (SNP) | VAF 199/692 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs201096259; called by muse, mutect2, varscan2
- PLPPR1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100883456; called by muse, mutect2, varscan2
- PLXNA4 | c.3979C>T p.P1327S | Missense Mutation (SNP) | VAF 204/351 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325333; called by muse, mutect2, varscan2
- POTEG | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 164/3667 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs764685202, COSV101612006; called by muse, mutect2
- PPP1R3A | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs267601239, COSV52888188; called by muse, mutect2, varscan2
- PRAMEF5 | c.288G>A p.R96= | Splice Region (SNP) | VAF 161/614 reads (26%) | catalogued as rs1553173602; called by muse, mutect2, varscan2
- PRAMEF6 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 209/537 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777181277; called by muse, mutect2, varscan2
- PRDM16 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 175/1056 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.963); catalogued as COSV54604113; called by muse, mutect2, varscan2
- PRDM8 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 152/599 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1273411289; called by muse, mutect2, varscan2
- PRSS35 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 108/384 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV63801016; called by muse, mutect2, varscan2
- PRUNE2 | c.5599C>T p.P1867S | Missense Mutation (SNP) | VAF 99/618 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV100944174, COSV65043586; called by muse, mutect2, varscan2
- PSD3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 188/455 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1204381287; called by muse, mutect2, varscan2
- PTCHD3 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 250/778 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71256391; called by muse, mutect2
- PTPRN2 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 281/524 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV67054242; called by muse, mutect2, varscan2
- PXDNL | c.3260C>T p.S1087L | Missense Mutation (SNP) | VAF 296/514 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV62481822, COSV62489591; called by muse, mutect2, varscan2
- PYGL | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 153/257 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs770642815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- R3HCC1 | c.505C>T p.R169C (on ENST00000411463; = p.R129C on NM_001136108.3) | Missense Mutation (SNP) | VAF 159/816 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753780437; called by muse, mutect2, varscan2
- RABL2B | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1262252948, COSV100711447; called by muse, mutect2, varscan2
- RAI2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 207/235 reads (88%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs989599739, COSV58966671; called by muse, mutect2, varscan2
- RCOR1 | c.78_104del p.A29_A37del | In Frame Del (DEL) | VAF 228/446 reads (51%) | catalogued as rs1346646439; called by mutect2, varscan2
- RELN | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.153); catalogued as rs777631168; called by muse, mutect2, varscan2
- RGPD3 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV100449972; called by muse, mutect2, varscan2
- RP1L1 | c.6139G>A p.D2047N | Missense Mutation (SNP) | VAF 185/636 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV66753076; called by muse, mutect2, varscan2
- SCN2A | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 97/654 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV51843296; called by muse, mutect2, varscan2
- SCN5A | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 131/479 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1060501141, COSV61116175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.2382G>A p.M794I | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as rs1403057447; called by muse, mutect2, varscan2
- SCN7A | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 195/704 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV101313423; called by muse, mutect2, varscan2
- SCN7A | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 65/527 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV69274793; called by muse, mutect2, varscan2
- SCNN1A | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 153/498 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs752542101; called by muse, mutect2, varscan2
- SEMA3A | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 117/427 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54869326; called by muse, mutect2, varscan2
- SERPINA11 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 133/445 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as COSV58241685; called by muse, varscan2
- SERPINA9 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 156/551 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs572837692, COSV100098259; called by muse, mutect2, varscan2
- SESTD1 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 190/237 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV58930529; called by muse, mutect2, varscan2
- SF3B2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 124/307 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1055874516; called by muse, mutect2, varscan2
- SLC11A1 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51915843; called by muse, mutect2, varscan2
- SLC16A8 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 159/352 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs758378855, COSV57635425; called by muse, mutect2, varscan2
- SLC22A13 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 155/317 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs757203550; called by muse, mutect2, varscan2
- SLC22A24 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 204/269 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs1308898788; called by muse, mutect2, varscan2
- SLC27A6 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 115/342 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1315273250, COSV52482732; called by muse, mutect2, varscan2
- SLC2A7 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 418/579 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.186); catalogued as rs1252804636; called by muse, mutect2, varscan2
- SLC4A1 | c.2055C>T p.T685= | Splice Region (SNP) | VAF 43/165 reads (26%) | catalogued as rs375136281; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A5 | c.1400G>A p.W467* | Nonsense Mutation (SNP) | VAF 124/148 reads (84%) | catalogued as rs867099087; called by muse, varscan2
- SLC6A9 | c.967C>T p.P323S (on ENST00000360584 / NM_201649.4; = p.P269S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 223/397 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62211630; called by muse, mutect2, varscan2
- SLCO5A1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 186/325 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs776943828, COSV52653397; called by muse, mutect2, varscan2
- SMAD6 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 89/672 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976407320, COSV99994362; called by muse, mutect2, varscan2
- SNRNP48 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 70/395 reads (18%) | catalogued as rs149913039; called by muse, mutect2, varscan2
- SPTLC3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65465339, COSV65466916; called by muse, mutect2, varscan2
- SYCP1 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs1430914392; called by muse, mutect2, varscan2
- SYNE1 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 276/334 reads (83%) | catalogued as COSV99582689; called by muse, mutect2, varscan2
- TAAR5 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 134/187 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57798880; called by muse, mutect2, varscan2
- TACSTD2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 116/369 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs529900062; called by muse, mutect2, varscan2
- THBS4 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 308/645 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100644206; called by muse, mutect2, varscan2
- TIE1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 195/361 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758194663, COSV65250549; called by muse, mutect2, varscan2
- TLR4 | c.1715C>T p.A572V (on ENST00000355622 / NM_138554.5; = p.A532V on NM_003266.4) | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs200676661; called by muse, mutect2, varscan2
- TRIM61 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 116/485 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV61418211; called by muse, mutect2, varscan2
- TRPA1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs368227098, COSV100085495; called by muse, mutect2, varscan2
- TRPC5 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 160/199 reads (80%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as COSV53304832; called by muse, mutect2, varscan2
- TSHZ2 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 245/649 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1377696400; called by muse, mutect2, varscan2
- TTC7A | c.2564C>A p.P855H | Missense Mutation (SNP) | VAF 182/237 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99766892, COSV99766972; called by muse, mutect2, varscan2
- TTN | c.52455G>A p.W17485* (on ENST00000591111; = p.W10061* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 197/246 reads (80%) | catalogued as rs1192054216; called by muse, mutect2, varscan2
- TTN | c.37291C>T p.R12431* (on ENST00000591111; = p.R5007* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 100/286 reads (35%) | catalogued as rs794729258, COSV60040131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B11 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 221/357 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs1157439248, COSV71424204; called by muse, mutect2, varscan2
- UMOD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 68/279 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV56778449; called by muse, mutect2, varscan2
- UNC13C | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 345/515 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV52895251, COSV99518746; called by muse, mutect2, varscan2
- UNC5B | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 179/216 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs755281605, COSV58980286; called by muse, mutect2, varscan2
- USF3 | c.5075C>T p.S1692F | Missense Mutation (SNP) | VAF 100/152 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs1376188976; called by muse, mutect2, varscan2
- USP32 | c.2785G>A p.D929N | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs1159360523; called by muse, mutect2, varscan2
- UVRAG | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV62110488; called by muse, mutect2, varscan2
- VPS35L | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 116/522 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs762761848; called by muse, mutect2
- VWA5B1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 183/524 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377682379; called by muse, mutect2, varscan2
- VWDE | c.3901C>T p.P1301S | Missense Mutation (SNP) | VAF 64/323 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV51736427; called by muse, mutect2, varscan2
- WASF2 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 77/429 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs368302587; called by muse, mutect2, varscan2
- ZBTB8B | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 144/486 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs564670427; called by mutect2, varscan2
- ZEB2 | c.1359G>T p.M453I | Missense Mutation (SNP) | VAF 107/700 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV104410550; called by mutect2, varscan2
- ZFHX2 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); catalogued as rs1199637098; called by muse, mutect2, varscan2
- ZFP42 | c.870T>A p.N290K | Missense Mutation (SNP) | VAF 189/367 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV100478814; called by muse, mutect2, varscan2
- ZFPM2 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 97/385 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65872626; called by muse, mutect2, varscan2
- ZFR2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 275/637 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1009774366; called by muse, mutect2, varscan2
- ZFR2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 332/784 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1366292421; called by muse, mutect2, varscan2
- ZNF311 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 355/852 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101014111; called by muse, mutect2, varscan2
- ZNF329 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 107/268 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV63771934; called by muse, mutect2, varscan2
- ZNF334 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 208/455 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV100749098; called by muse, mutect2, varscan2
- ZNF540 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 144/311 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.611); catalogued as rs768556407, COSV57107878; called by muse, mutect2, varscan2
- ZNF676 | c.361G>A p.D121N (on ENST00000650058; = p.D89N on NM_001001411.3) | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.389); catalogued as rs765977752, COSV68092063, COSV68095040; called by muse, mutect2, varscan2
- ZNF682 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 106/395 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as COSV62068464; called by muse, mutect2, varscan2
- ZNF711 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as rs867207957, COSV52157903; called by muse, mutect2, varscan2
- ZNF723 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs1198325222; called by muse, mutect2, varscan2
- ZNF831 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 279/645 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756739382, COSV64037250; called by muse, mutect2, varscan2
- ZZEF1 | c.7384C>T p.P2462S | Missense Mutation (SNP) | VAF 176/234 reads (75%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV67555975; called by muse, mutect2, varscan2
- A2ML1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACADL | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 175/215 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAM29 | c.1898G>A p.R633K | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS1 | c.2494C>T p.L832F | Missense Mutation (SNP) | VAF 207/559 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADAMTS13 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 158/572 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCYAP1 | c.455A>T p.K152I | Missense Mutation (SNP) | VAF 132/604 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRF1 | c.1705T>A p.F569I | Missense Mutation (SNP) | VAF 146/703 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ADGRG2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 71/162 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ADGRV1 | c.11429G>A p.G3810E | Missense Mutation (SNP) | VAF 93/525 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AHNAK2 | c.13946C>T p.S4649F | Missense Mutation (SNP) | VAF 79/441 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- AHNAK2 | c.13040G>A p.S4347N | Missense Mutation (SNP) | VAF 124/652 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.96); called by muse, varscan2
- AKT1 | c.50_53dup p.Y18* | Nonsense Mutation (INS) | VAF 55/276 reads (20%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.1666C>T p.L556F | Missense Mutation (SNP) | VAF 91/353 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ANKRD20A1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 166/525 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ARMC3 | c.2046-1G>A p.X682_splice | Splice Site (SNP) | VAF 124/379 reads (33%) | called by muse, mutect2, varscan2
- ARRDC4 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 147/824 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATP8A2 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 204/250 reads (82%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAIAP3 | c.2042G>A p.G681D | Missense Mutation (SNP) | VAF 195/386 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BCR | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 216/271 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- BEND2 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 239/282 reads (85%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- BRAP | c.507del p.A170Lfs*3 | Frame Shift Del (DEL) | VAF 239/535 reads (45%) | called by mutect2, pindel, varscan2
- BTBD7 | c.2407C>T p.H803Y | Missense Mutation (SNP) | VAF 156/588 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, varscan2
- CACNA1E | c.5728G>A p.E1910K | Missense Mutation (SNP) | VAF 235/861 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- CACNA1G | c.5156-1G>C p.X1719_splice | Splice Site (SNP) | VAF 173/295 reads (59%) | called by muse, mutect2, varscan2
- CCDC39 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 122/151 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CCDC51 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 327/387 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC66 | c.794C>T p.A265V (on ENST00000394672 / NM_001353147.1; = p.A231V on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/250 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- CCER1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 303/545 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CCN6 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 112/163 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CDC20 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CFAP47 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 119/269 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CFH | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 282/492 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CILP | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 66/487 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CLCN6 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 111/702 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNKSR1 | c.1111C>T p.P371S (on ENST00000374253 / NM_001297647.2; = p.P364S on NM_006314.3) | Missense Mutation (SNP) | VAF 121/852 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN5 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 132/170 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP3 | c.1690C>A p.Q564K | Missense Mutation (SNP) | VAF 161/310 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by mutect2, varscan2
- COL21A1 | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 186/446 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL22A1 | c.2821C>T p.L941F | Missense Mutation (SNP) | VAF 111/405 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL2A1 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 261/432 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL9A1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 116/439 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSE1L | c.2646T>G p.D882E | Missense Mutation (SNP) | VAF 180/391 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CSNK1G2 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 252/582 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CSTL1 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 100/534 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DCBLD2 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 132/444 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, varscan2
- DDX27 | c.830T>C p.L277S | Missense Mutation (SNP) | VAF 102/473 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIP2C | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 216/498 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DISP2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 351/486 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DISP2 | c.3396G>A p.W1132* | Nonsense Mutation (SNP) | VAF 258/765 reads (34%) | called by muse, mutect2, varscan2
- DNAH10 | c.7767G>A p.R2589= (on ENST00000409039; = p.R2528= on NM_207437.3) | Splice Region (SNP) | VAF 172/300 reads (57%) | called by muse, varscan2
- DNAH5 | c.2747A>C p.K916T | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH7 | c.10571C>T p.P3524L | Missense Mutation (SNP) | VAF 119/525 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1A | c.3418C>T p.P1140S | Missense Mutation (SNP) | VAF 115/479 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DPYD | c.2920G>A p.D974N | Missense Mutation (SNP) | VAF 115/140 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DPYD | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- DTX1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 177/346 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EFCAB5 | c.2664_2694del p.L889Tfs*12 | Frame Shift Del (DEL) | VAF 59/419 reads (14%) | called by mutect2, pindel
- ELAVL4 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 95/377 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENAM | c.3143G>A p.R1048K | Missense Mutation (SNP) | VAF 103/464 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ENOPH1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 235/448 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPP4 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 156/394 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- EPB41L5 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 80/697 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EQTN | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 155/392 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EYS | c.8402G>A p.G2801E (on ENST00000370621 / NM_001292009.1; = p.G2780E on NM_001142800.2) | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FAM110B | c.898A>C p.N300H | Missense Mutation (SNP) | VAF 240/427 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FAM53C | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 219/646 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM53C | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 217/644 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASTKD2 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- FBLN5 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FIG4 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FSD1L | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 122/378 reads (32%) | called by muse, mutect2, varscan2
- FSIP2 | c.5104G>A p.G1702R | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FYB2 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GCNT2 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 92/427 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCOM1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 325/464 reads (70%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GDPD4 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 220/825 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLDN | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 298/467 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLDN | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GNAO1 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 70/409 reads (17%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- GPATCH8 | c.2275C>T p.L759F | Missense Mutation (SNP) | VAF 156/529 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- GPC5 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 253/319 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- HABP2 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCN1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 119/376 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- HEATR1 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 174/251 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- HFM1 | c.3160_3178del p.A1054Rfs*4 | Frame Shift Del (DEL) | VAF 47/89 reads (53%) | called by mutect2, varscan2
- HMGA2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 80/377 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPG2 | c.6638C>T p.S2213L | Missense Mutation (SNP) | VAF 541/779 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ICOS | c.538T>G p.Y180D | Missense Mutation (SNP) | VAF 177/309 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-45 | c.116T>A p.V39D | Missense Mutation (SNP) | VAF 214/414 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, varscan2
- IL18RAP | c.1215A>T p.K405N | Missense Mutation (SNP) | VAF 191/314 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ILDR2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 102/710 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- INSYN2B | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 85/525 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IRAG2 | c.3848G>A p.G1283E (on ENST00000636465; = p.G328E on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1109 | c.14578G>T p.E4860* | Nonsense Mutation (SNP) | VAF 90/393 reads (23%) | called by muse, mutect2, varscan2
- KIF26B | c.5471G>A p.R1824Q | Missense Mutation (SNP) | VAF 582/803 reads (72%) | SIFT tolerated (0.61); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- KRT9 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 357/663 reads (54%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LAG3 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 194/721 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- LEPR | c.2900_2914del p.A967_E971del | In Frame Del (DEL) | VAF 104/410 reads (25%) | called by mutect2, pindel, varscan2
- LGI3 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- LLGL2 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMF1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 111/425 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LONRF2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 99/428 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, varscan2
- LRP1B | c.12890G>A p.G4297E | Missense Mutation (SNP) | VAF 233/407 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 109/1002 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUZP2 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 176/243 reads (72%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 485/1099 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- LYST | c.5365C>T p.H1789Y | Missense Mutation (SNP) | VAF 437/482 reads (91%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAB21L2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 115/448 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- MACF1 | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 162/301 reads (54%) | called by muse, mutect2, varscan2
- MAGEA1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 106/131 reads (81%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- MANEAL | c.1081G>C p.G361R (on ENST00000373045 / NM_001113482.1; = p.G139R on NM_152496.2) | Missense Mutation (SNP) | VAF 290/549 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1A | c.3905G>A p.G1302E | Missense Mutation (SNP) | VAF 317/530 reads (60%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAP3K20 | c.1562G>C p.R521T | Missense Mutation (SNP) | VAF 253/433 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MAP3K21 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 500/725 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MAP3K7CL | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 185/430 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.412); called by muse, mutect2
- MB | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 236/286 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- MED12 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 85/112 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- MGAM2 | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 91/406 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MMRN2 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 129/379 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MSI2 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MTHFD2 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 152/325 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC12 | c.8728C>T p.L2910F (on ENST00000379442; = p.L2767F on NM_001164462.1) | Missense Mutation (SNP) | VAF 106/2808 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2
- MXRA5 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 127/322 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO18A | c.6062A>G p.D2021G | Missense Mutation (SNP) | VAF 111/470 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYO9A | c.6143G>A p.C2048Y | Missense Mutation (SNP) | VAF 85/606 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCOA1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 153/210 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NDNF | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 253/432 reads (59%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- NECTIN3 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 94/140 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NELFA | c.810C>G p.I270M (on ENST00000542778; = p.I259M on NM_005663.5) | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- NEUROD1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 660/1278 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- NLRP7 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 231/605 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NMNAT1 | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 217/718 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NOL10 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 87/255 reads (34%) | called by muse, mutect2, varscan2
- OGDH | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 158/280 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OPRPN | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 111/406 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- OR13C2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 77/425 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- OR13F1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 218/387 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1J1 | c.55A>G p.I19V | Missense Mutation (SNP) | VAF 285/491 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR2M2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 93/412 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR51D1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 257/328 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51G1 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 93/312 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- OR52E1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 170/217 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OSTN | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 216/482 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.531A>C p.K177N (on ENST00000374531 / NM_001037293.2; = p.K209N on NM_053016.6) | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PCDHGB5 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 249/684 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PCED1B | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 256/468 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- PHAX | c.188T>G p.V63G | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PITHD1 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 282/768 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKP2 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 98/465 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- PLA2R1 | c.3317G>A p.G1106D | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHS1 | c.697G>A p.E233K (on ENST00000369310 / NM_182601.1; = p.E239K on NM_024889.5) | Missense Mutation (SNP) | VAF 121/161 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PNMA2 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 139/630 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- POFUT1 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 110/524 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PRDM16 | c.3515C>T p.T1172I | Missense Mutation (SNP) | VAF 207/577 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- PRKCQ | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 125/632 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTPRD | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 142/171 reads (83%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUS7L | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 211/345 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- RAPGEF5 | c.1733C>T p.P578L (on ENST00000401957 / NM_001367602.2; = p.P881L on NM_012294.5) | Missense Mutation (SNP) | VAF 123/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASEF | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 648/911 reads (71%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RASSF3 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 95/368 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- RBM24 | c.520G>A p.D174N (on ENST00000379052 / NM_001143942.2; = p.D129N on NM_153020.2) | Missense Mutation (SNP) | VAF 249/509 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RGL3 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 271/554 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIPK3 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 218/364 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- RNF165 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 137/534 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- RNF169 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 215/624 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF186 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 209/628 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- RP1 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- RUSC1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 235/796 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RUVBL1 | c.361+1del p.X121_splice | Splice Site (DEL) | VAF 77/290 reads (27%) | called by mutect2, pindel, varscan2
- SCARA3 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 225/485 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN11A | c.3434C>T p.S1145F | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SCN11A | c.3200T>A p.L1067Q | Missense Mutation (SNP) | VAF 100/435 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SCN11A | c.2949G>A p.K983= | Splice Region (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- SCN9A | c.5929G>A p.E1977K (on ENST00000303354; = p.E1966K on NM_002977.3) | Missense Mutation (SNP) | VAF 108/790 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SEMA5A | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 274/654 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SEPTIN8 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 87/505 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SESTD1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 191/238 reads (80%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- SLC12A3 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 207/449 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC16A1 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- SLC22A24 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 230/308 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC38A4 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 128/453 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SLC4A1 | c.2054C>T p.T685I | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC7A13 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 141/449 reads (31%) | called by muse, mutect2, varscan2
- SLC9C2 | c.3190T>G p.F1064V | Missense Mutation (SNP) | VAF 88/616 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLF1 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SLITRK5 | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 114/343 reads (33%) | called by muse, mutect2, varscan2
- SNAP91 | c.1445C>A p.P482Q | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SPATA16 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SPATA31A1 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 115/494 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SPTAN1 | c.5681C>T p.A1894V | Missense Mutation (SNP) | VAF 107/410 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SRCAP | c.3421C>T p.P1141S | Missense Mutation (SNP) | VAF 410/825 reads (50%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSUH2 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 186/231 reads (81%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ST8SIA5 | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 195/454 reads (43%) | PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- STAT1 | c.1804_1813del p.F603Afs*59 | Frame Shift Del (DEL) | VAF 111/483 reads (23%) | called by mutect2, pindel, varscan2
- STK11IP | c.2334C>T p.P778= | Splice Region (SNP) | VAF 90/230 reads (39%) | called by muse, mutect2, varscan2
- SYCE1L | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 194/489 reads (40%) | called by muse, mutect2
- TACR3 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 114/403 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TC2N | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCP11X2 | c.1288C>A p.R430S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); called by mutect2, varscan2
- TCP11X2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 184/483 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, varscan2
- TGOLN2 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 170/611 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2
- TMEM178B | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 107/422 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TMTC1 | c.805C>T p.P269S (on ENST00000539277 / NM_001193451.2; = p.P161S on NM_175861.3) | Missense Mutation (SNP) | VAF 294/659 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TNFAIP8 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 92/540 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TNFRSF25 | c.297C>T p.A99= | Splice Region (SNP) | VAF 99/552 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 112/689 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, varscan2
- TRANK1 | c.6155G>A p.R2052K | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV36DV7 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 169/310 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM36 | c.2008C>T p.L670F | Missense Mutation (SNP) | VAF 116/643 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM64B | c.1238A>C p.D413A | Missense Mutation (SNP) | VAF 114/1440 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- TRIM64B | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 165/791 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRIO | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 217/449 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TRIO | c.5113C>T p.P1705S | Missense Mutation (SNP) | VAF 103/436 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIOBP | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 173/493 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TSHZ2 | c.1891G>A p.G631S | Missense Mutation (SNP) | VAF 114/561 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.96547G>A p.D32183N (on ENST00000591111; = p.D24759N on NM_003319.4) | Missense Mutation (SNP) | VAF 162/388 reads (42%) | PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TUBB8B | c.716_745del p.C239_D249delinsY | In Frame Del (DEL) | VAF 116/738 reads (16%) | called by pindel, varscan2
- UGT8 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 106/444 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- UNC13C | c.2509T>G p.S837A | Missense Mutation (SNP) | VAF 366/544 reads (67%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- UNC5A | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 405/762 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP1 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 184/359 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- USP36 | c.2899C>G p.R967G | Missense Mutation (SNP) | VAF 137/501 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- USP36 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.319); called by muse, varscan2
- USP43 | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- WDR11 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- WNK3 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZBED9 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 102/514 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB47 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZC3H11B | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 82/1110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZFPM2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 150/470 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF257 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF302 | c.232T>G p.L78V (on ENST00000627982; = p.L77V on NM_018675.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ZNF462 | c.7354C>T p.H2452Y | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF536 | c.3895G>A p.G1299S | Missense Mutation (SNP) | VAF 116/137 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF804A | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 232/682 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF804B | c.3580A>T p.T1194S | Missense Mutation (SNP) | VAF 143/507 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF879 | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 219/611 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ABCA12 | c.6573G>A p.V2191= (on ENST00000272895 / NM_173076.3; = p.V1873= on NM_015657.3) | Silent (SNP) | VAF 201/270 reads (74%) | called by muse, mutect2, varscan2
- AC113554.1 | c.2067C>T p.S689= | Silent (SNP) | VAF 116/483 reads (24%) | called by muse, mutect2
- ACSF2 | c.1152G>A p.G384= | Silent (SNP) | VAF 84/360 reads (23%) | called by muse, mutect2, varscan2
- ADAM29 | c.1344C>T p.F448= | Silent (SNP) | VAF 123/454 reads (27%) | catalogued as rs768870601, COSV63660502; called by muse, mutect2, varscan2
- ADAMTS1 | c.2493C>T p.A831= | Silent (SNP) | VAF 208/564 reads (37%) | catalogued as rs1223347374; called by muse, mutect2, varscan2
- ADAMTS7 | c.1317C>T p.F439= | Silent (SNP) | VAF 235/380 reads (62%) | called by muse, mutect2, varscan2
- ADCK2 | c.1878G>C p.P626= | Silent (SNP) | VAF 181/329 reads (55%) | called by muse, mutect2
- ADGRF1 | c.1704C>A p.S568= | Silent (SNP) | VAF 143/703 reads (20%) | called by muse, mutect2, varscan2
- ADGRF4 | c.717C>T p.F239= | Silent (SNP) | VAF 126/563 reads (22%) | catalogued as rs774312102; called by muse, mutect2, varscan2
- ADGRG4 | c.6030C>T p.L2010= | Silent (SNP) | VAF 116/168 reads (69%) | catalogued as rs1355190822, COSV99795923; called by muse, mutect2, varscan2
- AGO3 | c.2253C>T p.L751= | Silent (SNP) | VAF 90/330 reads (27%) | catalogued as rs750383007, COSV55790929; called by muse, mutect2, varscan2
- AKAP3 | c.1476T>A p.I492= | Silent (SNP) | VAF 280/463 reads (60%) | called by muse, mutect2, varscan2
- ALAS1 | c.690C>T p.P230= | Silent (SNP) | VAF 98/248 reads (40%) | catalogued as COSV100050217; called by muse, mutect2, varscan2
- ALDH2 | c.1128G>A p.T376= | Silent (SNP) | VAF 271/471 reads (58%) | catalogued as rs182362882, COSV55666882; called by muse, mutect2, varscan2
- AMER3 | c.2154G>A p.E718= | Silent (SNP) | VAF 154/547 reads (28%) | called by muse, mutect2, varscan2
- ANAPC5 | c.1813C>T p.L605= | Silent (SNP) | VAF 280/493 reads (57%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2862T>G p.P954= | Silent (SNP) | VAF 120/267 reads (45%) | called by muse, mutect2, varscan2
- ANKS1B | c.993C>T p.L331= | Silent (SNP) | VAF 122/223 reads (55%) | called by muse, mutect2, varscan2
- AP1M1 | c.249C>T p.F83= | Silent (SNP) | VAF 104/477 reads (22%) | called by muse, mutect2, varscan2
- BAIAP3 | c.1893C>T p.T631= | Silent (SNP) | VAF 91/637 reads (14%) | catalogued as rs759828146; called by muse, mutect2, varscan2
- BICRA | c.3612C>T p.S1204= | Silent (SNP) | VAF 104/247 reads (42%) | called by muse, mutect2, varscan2
- BMP8A | c.897G>A p.Q299= | Silent (SNP) | VAF 125/420 reads (30%) | called by muse, mutect2, varscan2
- BTNL8 | c.1197C>T p.F399= | Silent (SNP) | VAF 396/757 reads (52%) | catalogued as rs1342754376, COSV51459471, COSV99180418; called by muse, mutect2, varscan2
- C5orf38 | c.165G>A p.G55= | Silent (SNP) | VAF 283/705 reads (40%) | called by muse, mutect2, varscan2
- C9orf131 | c.2886G>A p.R962= | Silent (SNP) | VAF 422/485 reads (87%) | called by muse, mutect2, varscan2
- CACNA1G | c.2142G>A p.R714= | Silent (SNP) | VAF 139/570 reads (24%) | catalogued as COSV61730587; called by muse, mutect2, varscan2
- CACNA1H | c.5406C>T p.F1802= | Silent (SNP) | VAF 345/649 reads (53%) | catalogued as rs537055062, COSV99327188; called by muse, mutect2, varscan2
- CALN1 | c.354G>A p.T118= (on ENST00000329008 / NM_001017440.3; = p.T160= on NM_031468.4) | Silent (SNP) | VAF 82/250 reads (33%) | catalogued as rs774302783, COSV61153391; called by muse, mutect2, varscan2
- CASKIN1 | c.1407G>A p.S469= | Silent (SNP) | VAF 220/544 reads (40%) | catalogued as rs778102586; called by muse, mutect2, varscan2
- CASZ1 | c.4509C>T p.F1503= | Silent (SNP) | VAF 596/816 reads (73%) | catalogued as rs957169851; called by muse, mutect2, varscan2
- CCDC168 | c.15426G>A p.E5142= | Silent (SNP) | VAF 135/344 reads (39%) | called by muse, mutect2, varscan2
- CCDC88B | c.2769G>A p.L923= | Silent (SNP) | VAF 219/288 reads (76%) | catalogued as rs1250417898; called by muse, mutect2, varscan2
- CCR3 | c.324C>T p.L108= | Silent (SNP) | VAF 165/206 reads (80%) | called by muse, mutect2, varscan2
- CDC20 | c.975C>T p.A325= | Silent (SNP) | VAF 99/398 reads (25%) | called by muse, mutect2, varscan2
- CDH8 | c.766C>T p.L256= | Silent (SNP) | VAF 233/567 reads (41%) | catalogued as COSV100181330, COSV54848603; called by muse, mutect2, varscan2
- CEP112 | c.303C>T p.I101= | Silent (SNP) | VAF 61/241 reads (25%) | called by muse, mutect2, varscan2
- CETN1 | c.210G>A p.K70= | Silent (SNP) | VAF 296/670 reads (44%) | catalogued as rs1267385470, COSV100511404; called by muse, mutect2
- CFAP46 | c.429C>T p.F143= | Silent (SNP) | VAF 103/280 reads (37%) | called by muse, mutect2, varscan2
- CFAP57 | c.3378C>T p.H1126= (on ENST00000372492 / NM_001378189.1; = p.H1159= on NM_001195831.3) | Silent (SNP) | VAF 195/394 reads (49%) | catalogued as rs889480879; called by muse, mutect2, varscan2
- CNKSR1 | c.1110C>T p.L370= (on ENST00000374253 / NM_001297647.2; = p.L363= on NM_006314.3) | Silent (SNP) | VAF 122/850 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.876C>T p.F292= | Silent (SNP) | VAF 83/473 reads (18%) | catalogued as rs778079652; called by muse, mutect2, varscan2
- COL2A1 | c.2406G>A p.E802= | Silent (SNP) | VAF 92/346 reads (27%) | called by muse, mutect2, varscan2
- COL4A4 | c.3861G>A p.L1287= | Silent (SNP) | VAF 284/342 reads (83%) | catalogued as COSV61632397; called by muse, mutect2, varscan2
- COL4A5 | c.1503C>T p.L501= | Silent (SNP) | VAF 114/148 reads (77%) | catalogued as COSV60371801; called by muse, mutect2, varscan2
- COL7A1 | c.5928G>A p.R1976= | Silent (SNP) | VAF 288/345 reads (83%) | catalogued as COSV60404635; called by muse, mutect2, varscan2
- CPNE2 | c.579C>T p.V193= | Silent (SNP) | VAF 111/445 reads (25%) | called by muse, mutect2, varscan2
- CREB3L3 | c.135C>T p.G45= | Silent (SNP) | VAF 166/408 reads (41%) | catalogued as rs746796362; called by muse, mutect2, varscan2
- CRYGB | c.172C>T p.L58= | Silent (SNP) | VAF 217/427 reads (51%) | catalogued as rs372576064; called by muse, mutect2, varscan2
- CYBB | c.735A>G p.E245= | Silent (SNP) | VAF 251/282 reads (89%) | called by muse, mutect2, varscan2
- CYBB | c.1248C>T p.F416= | Silent (SNP) | VAF 148/380 reads (39%) | catalogued as COSV66086326; called by muse, mutect2, varscan2
- CYP4F11 | c.1554C>T p.P518= | Silent (SNP) | VAF 130/336 reads (39%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.546G>A p.L182= | Silent (SNP) | VAF 167/238 reads (70%) | called by muse, mutect2, varscan2
- DCST2 | c.531G>A p.V177= | Silent (SNP) | VAF 257/471 reads (55%) | called by muse, mutect2, varscan2
- DLG2 | c.570C>T p.T190= | Silent (SNP) | VAF 382/665 reads (57%) | catalogued as rs140724117; called by muse, mutect2, varscan2
- DNAAF5 | c.1392C>T p.P464= | Silent (SNP) | VAF 128/579 reads (22%) | called by muse, mutect2, varscan2
- DOCK7 | c.279T>A p.P93= | Silent (SNP) | VAF 154/312 reads (49%) | called by muse, mutect2, varscan2
- DOCK8 | c.5121G>A p.E1707= | Silent (SNP) | VAF 122/515 reads (24%) | called by muse, mutect2, varscan2
- DPP6 | c.1374G>A p.G458= (on ENST00000377770 / NM_001364500.2; = p.G396= on NM_001936.5) | Silent (SNP) | VAF 93/334 reads (28%) | catalogued as COSV59599562; called by muse, mutect2, varscan2
- DYNC1H1 | c.3612C>T p.F1204= | Silent (SNP) | VAF 86/346 reads (25%) | called by muse, mutect2, varscan2
- EIF2S3B | c.627G>A p.A209= | Silent (SNP) | VAF 168/517 reads (32%) | catalogued as rs778023052, COSV59370544; called by muse, mutect2, varscan2
- EIF4G3 | c.66T>C p.A22= | Silent (SNP) | VAF 118/554 reads (21%) | called by muse, mutect2, varscan2
- ELF1 | c.1500C>T p.G500= | Silent (SNP) | VAF 285/379 reads (75%) | called by muse, mutect2, varscan2
- EMP1 | c.438C>T p.I146= | Silent (SNP) | VAF 109/411 reads (27%) | called by muse, mutect2, varscan2
- EPPK1 | c.5460G>A p.Q1820= | Silent (SNP) | VAF 139/498 reads (28%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.837C>T p.S279= | Silent (SNP) | VAF 197/469 reads (42%) | called by muse, mutect2, varscan2
- F11 | c.1386G>A p.G462= | Silent (SNP) | VAF 87/359 reads (24%) | catalogued as rs1177270376; called by muse, mutect2, varscan2
- FAM90A1 | c.213G>A p.P71= | Silent (SNP) | VAF 124/452 reads (27%) | catalogued as rs376865646; called by muse, mutect2, varscan2
- FARSA | c.1245C>T p.P415= | Silent (SNP) | VAF 212/508 reads (42%) | catalogued as rs1268635145, COSV100108958; called by muse, mutect2, varscan2
- FAT3 | c.2706G>A p.L902= | Silent (SNP) | VAF 90/203 reads (44%) | catalogued as COSV53154553; called by muse, mutect2, varscan2
- FBXL13 | c.699C>T p.L233= | Silent (SNP) | VAF 68/316 reads (22%) | called by muse, mutect2, varscan2
- FBXL8 | c.66G>A p.L22= | Silent (SNP) | VAF 265/614 reads (43%) | catalogued as rs1487470065; called by muse, mutect2, varscan2
- FCRL2 | c.201C>T p.F67= | Silent (SNP) | VAF 171/655 reads (26%) | catalogued as COSV63834831; called by muse, mutect2, varscan2
- FOXH1 | c.186G>A p.Q62= | Silent (SNP) | VAF 85/280 reads (30%) | called by muse, mutect2, varscan2
- FOXK2 | c.1767C>T p.V589= | Silent (SNP) | VAF 88/344 reads (26%) | called by muse, mutect2, varscan2
- GFRAL | c.1161G>A p.S387= | Silent (SNP) | VAF 141/355 reads (40%) | catalogued as rs1481994211, COSV61228830; called by muse, mutect2, varscan2
- GLB1L2 | c.687G>A p.L229= | Silent (SNP) | VAF 133/320 reads (42%) | called by muse, mutect2, varscan2
- GLCCI1 | c.36C>T p.S12= | Silent (SNP) | VAF 54/337 reads (16%) | called by muse, mutect2, varscan2
- GLDN | c.576G>A p.R192= | Silent (SNP) | VAF 295/462 reads (64%) | catalogued as rs772186962; called by muse, mutect2, varscan2
- GLI1 | c.297C>T p.I99= | Silent (SNP) | VAF 249/460 reads (54%) | catalogued as rs377645048; called by muse, mutect2, varscan2
- GMIP | c.1695C>T p.P565= | Silent (SNP) | VAF 235/518 reads (45%) | catalogued as COSV52555269; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1449G>A p.Q483= | Silent (SNP) | VAF 168/877 reads (19%) | called by muse, varscan2
- GP9 | c.348C>T p.P116= | Silent (SNP) | VAF 458/561 reads (82%) | called by muse, mutect2, varscan2
- GPR20 | c.192C>T p.F64= | Silent (SNP) | VAF 170/677 reads (25%) | catalogued as COSV66685286; called by muse, mutect2, varscan2
- GPR39 | c.141G>A p.G47= | Silent (SNP) | VAF 124/652 reads (19%) | catalogued as COSV100257141; called by muse, mutect2
- GRM3 | c.2355C>T p.F785= | Silent (SNP) | VAF 82/293 reads (28%) | catalogued as COSV64468946; called by muse, mutect2, varscan2
- GSTA5 | c.156C>T p.F52= | Silent (SNP) | VAF 168/417 reads (40%) | catalogued as COSV52861344; called by muse, mutect2, varscan2
- GTF2IRD2 | c.9G>A p.Q3= | Silent (SNP) | VAF 79/384 reads (21%) | called by muse, mutect2, varscan2
- H4-16 | c.187C>T p.L63= | Silent (SNP) | VAF 112/413 reads (27%) | catalogued as rs1468201685; called by muse, mutect2, varscan2
- HDAC9 | c.3045G>A p.R1015= (on ENST00000441542 / NM_178425.3; = p.R1012= on NM_178423.3) | Silent (SNP) | VAF 90/410 reads (22%) | catalogued as COSV101287088; called by muse, mutect2, varscan2
- HECW1 | c.87C>T p.S29= | Silent (SNP) | VAF 227/381 reads (60%) | called by muse, mutect2, varscan2
- HEPH | c.3027C>T p.F1009= (on ENST00000343002; = p.F742= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/262 reads (26%) | called by muse, mutect2, varscan2
- HTR1A | c.331C>T p.L111= | Silent (SNP) | VAF 108/634 reads (17%) | catalogued as rs748848484; called by muse, mutect2, varscan2
- IBTK | c.519C>T p.S173= | Silent (SNP) | VAF 71/301 reads (24%) | catalogued as rs749219780; called by muse, mutect2, varscan2
- IFNG | c.42C>T p.I14= | Silent (SNP) | VAF 201/355 reads (57%) | catalogued as rs778895202, COSV57491491; called by muse, mutect2, varscan2
- IPO13 | c.2286C>T p.P762= | Silent (SNP) | VAF 78/290 reads (27%) | catalogued as rs1474098373; called by muse, mutect2, varscan2
- ITGA8 | c.495G>A p.K165= | Silent (SNP) | VAF 191/717 reads (27%) | called by muse, mutect2, varscan2
- ITSN1 | c.384T>A p.A128= | Silent (SNP) | VAF 203/251 reads (81%) | called by muse, mutect2, varscan2
- JPH2 | c.2082C>T p.L694= | Silent (SNP) | VAF 201/504 reads (40%) | called by muse, mutect2, varscan2
- JPH2 | c.663C>T p.F221= | Silent (SNP) | VAF 296/671 reads (44%) | called by muse, mutect2, varscan2
- KAZN | c.1554C>T p.S518= | Silent (SNP) | VAF 150/470 reads (32%) | called by muse, mutect2, varscan2
- KCNK5 | c.1245C>T p.F415= | Silent (SNP) | VAF 148/742 reads (20%) | called by muse, mutect2, varscan2
- KCNT1 | c.1023G>A p.G341= (on ENST00000488444; = p.G360= on NM_020822.3) | Silent (SNP) | VAF 123/423 reads (29%) | called by muse, mutect2, varscan2
- KCTD7 | c.291C>T p.I97= | Silent (SNP) | VAF 65/298 reads (22%) | catalogued as rs769023482; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KDR | c.2148G>A p.K716= | Silent (SNP) | VAF 157/325 reads (48%) | catalogued as COSV55761251; called by muse, mutect2, varscan2
- KIAA1109 | c.1743C>T p.F581= | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as COSV99145303; called by muse, varscan2
- KRT1 | c.546G>A p.E182= | Silent (SNP) | VAF 84/205 reads (41%) | catalogued as rs1284384456; called by muse, mutect2, varscan2
- KRT15 | c.984G>A p.T328= | Silent (SNP) | VAF 122/457 reads (27%) | catalogued as rs768767508; called by muse, mutect2, varscan2
- KRT32 | c.1176G>A p.E392= | Silent (SNP) | VAF 125/427 reads (29%) | called by muse, mutect2, varscan2
- KSR2 | c.1101C>T p.S367= | Silent (SNP) | VAF 132/461 reads (29%) | called by muse, mutect2, varscan2
- LAG3 | c.345C>T p.P115= | Silent (SNP) | VAF 194/721 reads (27%) | catalogued as rs1205171938; called by muse, mutect2, varscan2
- LAMA4 | c.1269C>T p.A423= (on ENST00000230538 / NM_001105206.3; = p.A416= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/179 reads (68%) | called by muse, mutect2, varscan2
- LARS1 | c.2295C>T p.L765= (on ENST00000394434 / NM_020117.11; = p.L738= on NM_016460.3) | Silent (SNP) | VAF 115/723 reads (16%) | catalogued as rs1554127663, COSV50974609; ClinVar: likely benign; called by muse, mutect2, varscan2
- LGI3 | c.825C>T p.I275= | Silent (SNP) | VAF 71/301 reads (24%) | called by muse, mutect2, varscan2
- LILRA1 | c.297C>T p.F99= | Silent (SNP) | VAF 83/206 reads (40%) | called by muse, mutect2, varscan2
- LINC02218 | c.399G>A p.S133= | Silent (SNP) | VAF 224/506 reads (44%) | catalogued as rs565095819; called by muse, mutect2, varscan2
- LOXHD1 | c.2595C>T p.F865= | Silent (SNP) | VAF 122/219 reads (56%) | called by muse, mutect2, varscan2
- LRP1B | c.3891C>T p.F1297= | Silent (SNP) | VAF 85/334 reads (25%) | catalogued as COSV101251917; called by muse, mutect2, varscan2
- LRRC1 | c.480G>A p.E160= | Silent (SNP) | VAF 83/446 reads (19%) | catalogued as COSV63829952; called by muse, mutect2, varscan2
- LRRC6 | c.955C>T p.L319= | Silent (SNP) | VAF 71/288 reads (25%) | catalogued as COSV51537898; called by muse, mutect2, varscan2
- LUC7L3 | c.618C>T p.S206= | Silent (SNP) | VAF 124/416 reads (30%) | called by muse, mutect2, varscan2
- MAK | c.1332A>G p.V444= | Silent (SNP) | VAF 80/332 reads (24%) | called by muse, mutect2, varscan2
- MALRD1 | c.4938G>A p.R1646= | Silent (SNP) | VAF 399/695 reads (57%) | catalogued as COSV65985391; called by muse, mutect2, varscan2
- MAN2A2 | c.1666C>T p.L556= | Silent (SNP) | VAF 419/654 reads (64%) | called by muse, mutect2, varscan2
- MAP7 | c.1506G>A p.R502= | Silent (SNP) | VAF 97/250 reads (39%) | catalogued as rs756261293; called by muse, mutect2, varscan2
- MAPKBP1 | c.2847C>T p.P949= (on ENST00000456763 / NM_001128608.2; = p.P943= on NM_014994.3) | Silent (SNP) | VAF 411/586 reads (70%) | catalogued as COSV99530365; called by muse, mutect2, varscan2
- MGAM | c.3456G>A p.G1152= | Silent (SNP) | VAF 120/476 reads (25%) | catalogued as COSV101527423; called by muse, mutect2, varscan2
- MINAR1 | c.1164C>T p.P388= | Silent (SNP) | VAF 113/517 reads (22%) | called by muse, mutect2, varscan2
- MIP | c.435C>T p.I145= | Silent (SNP) | VAF 277/497 reads (56%) | catalogued as COSV99234180; called by muse, mutect2, varscan2
- MOS | c.423C>T p.F141= | Silent (SNP) | VAF 162/289 reads (56%) | catalogued as COSV61337020; called by muse, mutect2, varscan2
- MUC22 | c.624C>T p.V208= | Silent (SNP) | VAF 222/981 reads (23%) | called by muse, mutect2, varscan2
- MYBL2 | c.1695C>T p.P565= | Silent (SNP) | VAF 169/377 reads (45%) | catalogued as rs554383813, COSV53827401; called by muse, mutect2, varscan2
- MYH1 | c.5115C>T p.I1705= | Silent (SNP) | VAF 293/368 reads (80%) | catalogued as rs145122906, COSV56844388; called by muse, mutect2, varscan2
- MYO3A | c.4539A>T p.L1513= | Silent (SNP) | VAF 83/434 reads (19%) | called by muse, mutect2, varscan2
- MYO7A | c.4251C>T p.I1417= | Silent (SNP) | VAF 118/875 reads (13%) | catalogued as rs397516307; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYT1 | c.3090C>T p.S1030= | Silent (SNP) | VAF 105/500 reads (21%) | catalogued as COSV100113920; called by muse, mutect2, varscan2
- NAP1L2 | c.135G>A p.G45= | Silent (SNP) | VAF 130/150 reads (87%) | catalogued as COSV100999198; called by muse, mutect2, varscan2
- NCKAP5L | c.711C>T p.P237= | Silent (SNP) | VAF 161/620 reads (26%) | catalogued as COSV60131227; called by muse, mutect2, varscan2
- NLRP10 | c.1446G>A p.E482= | Silent (SNP) | VAF 147/381 reads (39%) | catalogued as rs150008504; called by muse, mutect2, varscan2
- NOVA1 | c.1137G>A p.T379= | Silent (SNP) | VAF 263/446 reads (59%) | catalogued as rs144344947, COSV57478512; called by muse, mutect2, varscan2
- NPAS2 | c.108C>T p.L36= | Silent (SNP) | VAF 245/419 reads (58%) | called by muse, mutect2, varscan2
- NPFFR2 | c.927G>A p.R309= | Silent (SNP) | VAF 296/533 reads (56%) | catalogued as COSV100441457; called by muse, mutect2, varscan2
- NPR1 | c.2262G>A p.R754= | Silent (SNP) | VAF 107/657 reads (16%) | catalogued as rs1393531440; called by muse, mutect2, varscan2
- NTRK3 | c.1044C>T p.I348= | Silent (SNP) | VAF 159/659 reads (24%) | catalogued as rs771618238, COSV100448256; called by muse, mutect2, varscan2
- OGDHL | c.579C>T p.I193= | Silent (SNP) | VAF 161/205 reads (79%) | catalogued as rs768018300, COSV104427187; called by muse, mutect2, varscan2
- OOSP2 | c.183G>A p.R61= | Silent (SNP) | VAF 209/269 reads (78%) | called by muse, mutect2, varscan2
- OR10J1 | c.234C>T p.L78= | Silent (SNP) | VAF 219/735 reads (30%) | catalogued as rs766089577; called by muse, mutect2, varscan2
- OR13C9 | c.255C>T p.F85= | Silent (SNP) | VAF 344/549 reads (63%) | catalogued as COSV52241005; called by muse, mutect2, varscan2
- OR2G3 | c.813G>A p.G271= | Silent (SNP) | VAF 259/405 reads (64%) | catalogued as COSV60682370; called by muse, mutect2, varscan2
- OR56B1 | c.270C>T p.I90= | Silent (SNP) | VAF 103/246 reads (42%) | catalogued as COSV100402548; called by muse, mutect2, varscan2
- OR5D13 | c.885G>A p.R295= | Silent (SNP) | VAF 65/199 reads (33%) | catalogued as rs1295811448, COSV62332673; called by muse, mutect2, varscan2
- PACSIN2 | c.1257C>T p.F419= | Silent (SNP) | VAF 253/317 reads (80%) | catalogued as rs754533087, COSV54321242; called by muse, mutect2, varscan2
- PANX2 | c.1593G>A p.A531= | Silent (SNP) | VAF 175/431 reads (41%) | catalogued as rs1181044874; called by muse, mutect2, varscan2
- PCDHA8 | c.1237C>T p.L413= | Silent (SNP) | VAF 495/529 reads (94%) | catalogued as COSV65340933; called by muse, mutect2, varscan2
- PCDHB11 | c.1086G>A p.E362= | Silent (SNP) | VAF 108/604 reads (18%) | catalogued as COSV61314182; called by muse, mutect2, varscan2
- PCDHB13 | c.528C>T p.N176= | Silent (SNP) | VAF 287/592 reads (48%) | called by muse, mutect2, varscan2
- PCDHB16 | c.2010C>T p.F670= | Silent (SNP) | VAF 197/1134 reads (17%) | catalogued as rs781892594; called by muse, mutect2, varscan2
- PCDHGA7 | c.225C>T p.F75= | Silent (SNP) | VAF 162/889 reads (18%) | catalogued as COSV54053472; called by muse, mutect2, varscan2
- PELP1 | c.339C>T p.S113= | Silent (SNP) | VAF 241/298 reads (81%) | catalogued as COSV52592460; called by muse, mutect2, varscan2
- PF4 | c.240G>A p.R80= | Silent (SNP) | VAF 175/354 reads (49%) | catalogued as rs4694, COSV56020807; called by muse, mutect2, varscan2
- PGK2 | c.966G>A p.K322= | Silent (SNP) | VAF 110/550 reads (20%) | called by muse, mutect2, varscan2
- PHB | c.198C>T p.I66= | Silent (SNP) | VAF 73/327 reads (22%) | called by muse, mutect2, varscan2
- PHETA1 | c.483C>T p.S161= | Silent (SNP) | VAF 145/553 reads (26%) | called by muse, mutect2, varscan2
- PIWIL4 | c.2520A>G p.E840= | Silent (SNP) | VAF 179/217 reads (82%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1974C>T p.V658= | Silent (SNP) | VAF 103/374 reads (28%) | called by muse, mutect2, varscan2
- PLB1 | c.567G>A p.A189= | Silent (SNP) | VAF 283/338 reads (84%) | catalogued as rs756041365; called by muse, mutect2, varscan2
- PLEKHG4B | c.2029C>T p.L677= (on ENST00000283426; = p.L1033= on NM_052909.5) | Silent (SNP) | VAF 157/1081 reads (15%) | called by muse, mutect2, varscan2
- PLXNA3 | c.3939C>T p.A1313= | Silent (SNP) | VAF 131/175 reads (75%) | called by muse, mutect2, varscan2
- PLXNB2 | c.2664C>T p.V888= | Silent (SNP) | VAF 110/267 reads (41%) | called by muse, mutect2, varscan2
- PPP1R26 | c.777C>T p.S259= | Silent (SNP) | VAF 240/445 reads (54%) | catalogued as rs149335898, COSV63354742; called by muse, mutect2, varscan2
- PPP2R5C | c.75G>A p.V25= | Silent (SNP) | VAF 105/382 reads (27%) | called by muse, mutect2, varscan2
- PPT2 | c.790T>C p.L264= | Silent (SNP) | VAF 149/688 reads (22%) | called by muse, mutect2, varscan2
- PRDM13 | c.573C>T p.S191= | Silent (SNP) | VAF 149/557 reads (27%) | called by muse, mutect2, varscan2
- PRDM9 | c.909G>A p.E303= | Silent (SNP) | VAF 195/441 reads (44%) | catalogued as rs754351359, COSV57012964; called by muse, mutect2, varscan2
- PRKAA2 | c.1026C>T p.L342= | Silent (SNP) | VAF 103/426 reads (24%) | catalogued as rs756393902, COSV64802336; called by muse, mutect2, varscan2
- PRKCQ | c.474G>A p.K158= | Silent (SNP) | VAF 124/626 reads (20%) | catalogued as rs1564354133; called by muse, mutect2, varscan2
- PSAPL1 | c.525C>T p.P175= | Silent (SNP) | VAF 443/506 reads (88%) | called by muse, mutect2, varscan2
- PTK2B | c.603C>T p.F201= | Silent (SNP) | VAF 133/639 reads (21%) | catalogued as rs145177380, COSV57761551; called by muse, mutect2, varscan2
- PTPRR | c.1461G>A p.V487= | Silent (SNP) | VAF 107/382 reads (28%) | catalogued as COSV51728880; called by muse, mutect2, varscan2
- PXDN | c.3738G>A p.G1246= | Silent (SNP) | VAF 148/194 reads (76%) | called by muse, mutect2, varscan2
- PXDN | c.1173C>T p.I391= | Silent (SNP) | VAF 168/441 reads (38%) | called by muse, mutect2, varscan2
- PZP | c.747C>T p.V249= | Silent (SNP) | VAF 99/362 reads (27%) | called by muse, mutect2, varscan2
- RASGRF1 | c.570C>T p.S190= | Silent (SNP) | VAF 128/540 reads (24%) | called by muse, mutect2, varscan2
- RBM33 | c.3504C>T p.I1168= | Silent (SNP) | VAF 76/338 reads (22%) | catalogued as rs139259621; called by muse, mutect2, varscan2
- RDM1 | c.324C>T p.A108= | Silent (SNP) | VAF 242/418 reads (58%) | called by muse, mutect2, varscan2
- RELN | c.429C>T p.F143= | Silent (SNP) | VAF 109/374 reads (29%) | catalogued as rs755809338, COSV100633827; called by muse, mutect2, varscan2
- RGS5 | c.36C>T p.I12= | Silent (SNP) | VAF 113/754 reads (15%) | catalogued as rs1324621611; called by muse, mutect2, varscan2
- ROBO2 | c.3969C>T p.F1323= | Silent (SNP) | VAF 101/481 reads (21%) | catalogued as rs267599937, COSV59904632; called by muse, mutect2, varscan2
- RP1 | c.2148G>A p.Q716= | Silent (SNP) | VAF 212/363 reads (58%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.966C>T p.I322= | Silent (SNP) | VAF 161/421 reads (38%) | catalogued as COSV99590080; called by muse, mutect2, varscan2
- SALL1 | c.2235G>A p.T745= | Silent (SNP) | VAF 111/584 reads (19%) | catalogued as rs778105407, COSV51752928; called by muse, mutect2, varscan2
- SALL1 | c.780G>A p.Q260= | Silent (SNP) | VAF 230/518 reads (44%) | called by muse, mutect2, varscan2
- SALL3 | c.282C>T p.F94= | Silent (SNP) | VAF 231/560 reads (41%) | catalogued as COSV73305846, COSV73306453; called by muse, mutect2, varscan2
- SEL1L2 | c.2055T>C p.N685= | Silent (SNP) | VAF 55/265 reads (21%) | called by muse, mutect2, varscan2
- SERPINA11 | c.846G>A p.G282= | Silent (SNP) | VAF 244/403 reads (61%) | catalogued as COSV58241166; called by muse, varscan2
- SERPINA6 | c.1191C>T p.F397= | Silent (SNP) | VAF 128/435 reads (29%) | catalogued as rs267604110, COSV58583411, COSV58583818; called by muse, mutect2, varscan2
- SHH | c.423C>T p.Y141= | Silent (SNP) | VAF 167/529 reads (32%) | catalogued as rs763132615, COSV51920281; called by muse, mutect2, varscan2
- SHROOM3 | c.3540C>T p.L1180= | Silent (SNP) | VAF 155/580 reads (27%) | catalogued as rs1318171273, COSV56028837; called by muse, mutect2, varscan2
- SLC29A2 | c.1119C>T p.P373= | Silent (SNP) | VAF 285/356 reads (80%) | catalogued as COSV60803347; called by muse, mutect2, varscan2
- SLC2A14 | c.1512C>T p.V504= | Silent (SNP) | VAF 79/179 reads (44%) | called by muse, mutect2, varscan2
- SLC2A3 | c.1440C>T p.V480= | Silent (SNP) | VAF 140/728 reads (19%) | catalogued as rs769424892; called by muse, mutect2
- SLC35D3 | c.702G>A p.L234= | Silent (SNP) | VAF 130/596 reads (22%) | called by muse, mutect2, varscan2
- SP6 | c.42G>A p.T14= | Silent (SNP) | VAF 107/403 reads (27%) | called by muse, mutect2, varscan2
- SPAG4 | c.462G>A p.L154= | Silent (SNP) | VAF 98/550 reads (18%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.975G>A p.Q325= | Silent (SNP) | VAF 211/681 reads (31%) | called by muse, mutect2, varscan2
- SPTA1 | c.864C>T p.T288= | Silent (SNP) | VAF 210/719 reads (29%) | catalogued as rs1443486470, COSV63756904; called by muse, mutect2, varscan2
- SPTBN2 | c.4137C>T p.L1379= | Silent (SNP) | VAF 279/355 reads (79%) | called by muse, mutect2, varscan2
- STAT2 | c.2424C>T p.N808= | Silent (SNP) | VAF 185/328 reads (56%) | called by muse, mutect2, varscan2
- STAU1 | c.945C>T p.R315= (on ENST00000371856 / NM_001319135.1; = p.R234= on NM_004602.3) | Silent (SNP) | VAF 105/453 reads (23%) | called by muse, mutect2, varscan2
- TAF11L3 | c.564C>T p.F188= | Silent (SNP) | VAF 137/592 reads (23%) | called by muse, mutect2, varscan2
- TAF1L | c.1660C>T p.L554= | Silent (SNP) | VAF 149/379 reads (39%) | catalogued as rs771747922, COSV54260347; called by muse, mutect2, varscan2
- TBPL2 | c.720G>A p.R240= | Silent (SNP) | VAF 97/369 reads (26%) | called by muse, mutect2, varscan2
- TGM4 | c.108C>T p.F36= | Silent (SNP) | VAF 112/259 reads (43%) | called by muse, mutect2, varscan2
- TLR8 | c.1524C>T p.A508= (on ENST00000218032 / NM_138636.5; = p.A526= on NM_016610.4) | Silent (SNP) | VAF 95/255 reads (37%) | called by muse, mutect2, varscan2
- TMEM165 | c.42C>T p.P14= | Silent (SNP) | VAF 82/516 reads (16%) | catalogued as rs750639132; called by muse, mutect2, varscan2
- TMEM182 | c.655C>T p.L219= | Silent (SNP) | VAF 169/325 reads (52%) | catalogued as COSV68425387; called by muse, mutect2, varscan2
- TOPAZ1 | c.1959C>T p.N653= | Silent (SNP) | VAF 80/267 reads (30%) | called by muse, mutect2, varscan2
- TPD52L1 | c.588G>A p.R196= | Silent (SNP) | VAF 104/148 reads (70%) | called by muse, mutect2, varscan2
- TRABD2B | c.1017C>T p.I339= | Silent (SNP) | VAF 86/337 reads (26%) | catalogued as rs1277516242, COSV71110849; called by muse, mutect2, varscan2
- TRMT44 | c.1800C>T p.N600= | Silent (SNP) | VAF 293/515 reads (57%) | called by muse, mutect2, varscan2
- TTC28 | c.1224G>A p.R408= | Silent (SNP) | VAF 148/368 reads (40%) | called by muse, mutect2, varscan2
- UBQLN4 | c.882C>T p.F294= | Silent (SNP) | VAF 161/645 reads (25%) | called by muse, mutect2, varscan2
- ULK3 | c.1053C>T p.S351= | Silent (SNP) | VAF 105/738 reads (14%) | called by muse, mutect2, varscan2
- UNC13A | c.1668C>T p.F556= | Silent (SNP) | VAF 168/726 reads (23%) | catalogued as COSV53191217; called by muse, mutect2, varscan2
- UPF1 | c.2469C>T p.S823= (on ENST00000599848 / NM_001297549.2; = p.S812= on NM_002911.4) | Silent (SNP) | VAF 92/359 reads (26%) | called by muse, mutect2, varscan2
- USH1C | c.282C>T p.H94= | Silent (SNP) | VAF 266/332 reads (80%) | catalogued as rs554615192; called by muse, mutect2, varscan2
- VARS1 | c.1485G>C p.L495= | Silent (SNP) | VAF 271/675 reads (40%) | catalogued as COSV65154967; called by muse, mutect2, varscan2
- VPS50 | c.1236C>T p.F412= | Silent (SNP) | VAF 60/215 reads (28%) | called by muse, mutect2, varscan2
- WDR4 | c.819G>A p.L273= | Silent (SNP) | VAF 192/245 reads (78%) | called by muse, mutect2, varscan2
- WDR90 | c.3771C>T p.F1257= | Silent (SNP) | VAF 188/1074 reads (18%) | called by muse, mutect2
- XKR9 | c.792G>A p.R264= | Silent (SNP) | VAF 181/278 reads (65%) | catalogued as rs772216324; called by muse, mutect2, varscan2
- XPO6 | c.2533C>T p.L845= | Silent (SNP) | VAF 86/352 reads (24%) | called by muse, mutect2, varscan2
- ZBED9 | c.2067G>A p.A689= | Silent (SNP) | VAF 53/323 reads (16%) | catalogued as rs1019403596, COSV71729372; called by muse, mutect2, varscan2
- ZBTB11 | c.2808C>T p.F936= | Silent (SNP) | VAF 120/769 reads (16%) | catalogued as COSV57245063; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2167C>T p.L723= | Silent (SNP) | VAF 56/249 reads (22%) | called by muse, mutect2, varscan2
- ZDBF2 | c.375G>A p.Q125= | Silent (SNP) | VAF 124/439 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.816G>A p.G272= | Silent (SNP) | VAF 121/450 reads (27%) | called by muse, mutect2, varscan2
- ZMYND19 | c.519C>T p.P173= | Silent (SNP) | VAF 134/290 reads (46%) | called by muse, mutect2, varscan2
- ZNF200 | c.663C>T p.T221= | Silent (SNP) | VAF 202/458 reads (44%) | called by muse, mutect2, varscan2
- ZNF418 | c.1986C>T p.L662= | Silent (SNP) | VAF 199/245 reads (81%) | catalogued as COSV68675733; called by muse, mutect2, varscan2
- ZNF479 | c.966G>A p.E322= | Silent (SNP) | VAF 108/470 reads (23%) | catalogued as COSV100482655, COSV58642687; called by muse, mutect2, varscan2
- ZNF730 | c.459C>T p.V153= | Silent (SNP) | VAF 81/254 reads (32%) | catalogued as rs758074465; called by muse, mutect2, varscan2
- ZNF786 | c.495C>T p.I165= | Silent (SNP) | VAF 160/542 reads (30%) | catalogued as rs370763414; called by muse, mutect2, varscan2
- ZSWIM2 | c.1901G>A p.*634= | Silent (SNP) | VAF 36/221 reads (16%) | catalogued as rs1486886545; called by muse, mutect2, varscan2
- ZSWIM6 | c.1339C>T p.L447= | Silent (SNP) | VAF 57/349 reads (16%) | called by muse, mutect2, varscan2
- ABCC9 | c.406+2102G>A | Intron (SNP) | VAF 75/325 reads (23%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3302A>T | Intron (SNP) | VAF 110/399 reads (28%) | called by muse, mutect2, varscan2
- BEST3 | c.1100+974G>A | Intron (SNP) | VAF 66/250 reads (26%) | catalogued as COSV100437781; called by muse, mutect2, varscan2
- C5orf67 | n.426T>G | RNA (SNP) | VAF 72/446 reads (16%) | called by muse, mutect2, varscan2
- CHN1 | c.550-44C>G | Intron (SNP) | VAF 170/509 reads (33%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2562G>A | Intron (SNP) | VAF 365/460 reads (79%) | catalogued as rs367635678; called by muse, mutect2, varscan2
- HTR4 | c.1077-1066G>A | Intron (SNP) | VAF 87/414 reads (21%) | called by muse, mutect2, varscan2
- HUNK | c.*1232C>T | 3'UTR (SNP) | VAF 205/493 reads (42%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3525G>A | Intron (SNP) | VAF 255/1700 reads (15%) | catalogued as COSV55177973; called by muse, varscan2
- IQCJ-SCHIP1 | c.988-26161G>A | Intron (SNP) | VAF 203/342 reads (59%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+25244G>A | Intron (SNP) | VAF 78/239 reads (33%) | called by muse, mutect2, varscan2
- MAFB | c.*1035C>T | 3'UTR (SNP) | VAF 104/504 reads (21%) | called by muse, mutect2, varscan2
- MIR646HG | n.226G>A | RNA (SNP) | VAF 86/399 reads (22%) | called by muse, mutect2, varscan2
- MLIP | c.64-9942G>A | Intron (SNP) | VAF 89/418 reads (21%) | called by muse, mutect2, varscan2
- MT3 | c.97+172C>T | Intron (SNP) | VAF 156/354 reads (44%) | called by muse, mutect2, varscan2
- PEG10 | c.*673C>T | 3'UTR (SNP) | VAF 190/334 reads (57%) | called by muse, mutect2, varscan2
- PSD3 | c.2176-28116C>T | Intron (SNP) | VAF 63/297 reads (21%) | catalogued as rs1485322900; called by muse, mutect2, varscan2
- RGS4 | chr1:163068988 C>T | 5'Flank (SNP) | VAF 211/530 reads (40%) | catalogued as rs1167784342; called by muse, mutect2, varscan2
- RGS4 | chr1:163068989 C>T | 5'Flank (SNP) | VAF 212/531 reads (40%) | catalogued as rs915009388; called by muse, mutect2, varscan2
- RNF213 | c.3024+138C>T | Intron (SNP) | VAF 109/381 reads (29%) | catalogued as rs774099533, COSV100173585; called by muse, mutect2, varscan2
- SEBOX | c.-77G>A | 5'UTR (SNP) | VAF 68/229 reads (30%) | catalogued as rs782198756, COSV52645724; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23835C>T | Intron (SNP) | VAF 40/225 reads (18%) | catalogued as COSV101043715; called by muse, mutect2, varscan2
- SMAD4 | c.-98C>T | 5'UTR (SNP) | VAF 78/209 reads (37%) | catalogued as rs1166995278; called by muse, mutect2, varscan2
- SOHLH1 | c.*593G>A | 3'UTR (SNP) | VAF 273/466 reads (59%) | called by muse, mutect2, varscan2
- SOX11 | c.*84G>A | 3'UTR (SNP) | VAF 100/229 reads (44%) | called by muse, varscan2
- STEAP1B | c.706-18813G>A | Intron (SNP) | VAF 224/581 reads (39%) | catalogued as rs1200150089; called by muse, mutect2, varscan2
- SYT7 | c.215+8811G>A | Intron (SNP) | VAF 65/174 reads (37%) | called by muse, mutect2, varscan2
- TLE5 | chr19:3062708 C>T | 5'Flank (SNP) | VAF 180/375 reads (48%) | called by muse, mutect2, varscan2
- UNC13B | c.762-3075C>T | Intron (SNP) | VAF 243/277 reads (88%) | called by muse, mutect2, varscan2
- XIRP2 | c.*752G>A | 3'UTR (SNP) | VAF 284/579 reads (49%) | catalogued as COSV54737325; called by muse, mutect2, varscan2
